Somatic mutation profile of tumor specimen TCGA-V4-A9EQ-01A (aliquot TCGA-V4-A9EQ-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EQ, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.1 years (23,408 days).
Specimen TCGA-V4-A9EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05c19b64-2805-4eb8-9534-8b798b83f65d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EQ-10A (Blood Derived Normal), aliquot TCGA-V4-A9EQ-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ec0c00b-b95d-48ea-80d0-ac0cc0e73e6e

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BTNL3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1468570079, COSV61564583; called by muse, mutect2, varscan2
- FAM161A | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs911408597, COSV56764701; called by muse, mutect2, varscan2
- GSTA4 | c.323T>A p.M108K | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV63955304; called by muse, mutect2, varscan2
- MC2R | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1383119237, COSV59617328; called by muse, mutect2, varscan2
- NPHP3 | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV58628737; called by muse, mutect2, varscan2
- SLC4A1 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV52258880, COSV99293214; called by mutect2, varscan2
- VWA5A | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs767909087, COSV63707332; called by muse, mutect2, varscan2
- ABCA6 | c.1341T>C p.N447= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- NEDD9 | c.255C>T p.T85= | Silent (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- SH3RF2 | c.1107C>T p.A369= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs770613982; called by muse, mutect2, varscan2
- TRAV8-2 | c.9G>C p.L3= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2
